Somatic mutation profile of tumor specimen TCGA-YT-A95F-01A (aliquot TCGA-YT-A95F-01A-11D-A428-09) from TCGA case TCGA-YT-A95F, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 55.8 years (20,363 days).
Specimen TCGA-YT-A95F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db673ddb-7655-41d0-ab2d-5162458bb3b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YT-A95F-10A (Blood Derived Normal), aliquot TCGA-YT-A95F-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fac65691-5bdb-444c-89b9-941b3773cfbd

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1, Intron 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 64/448 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- ENKUR | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as rs928354172; called by muse, mutect2, varscan2
- HDAC4 | c.2238C>A p.F746L | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs753482334, COSV61860486, COSV61869956; called by muse, mutect2
- HEBP2 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770263401; called by mutect2, varscan2
- LAMB1 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1211070549; called by muse, varscan2
- NES | c.3167C>T p.P1056L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100957732, COSV100957781; called by muse, mutect2, varscan2
- OPALIN | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.318); catalogued as COSV100959718; called by mutect2, varscan2
- PNISR | c.2083_2086del p.Q695Kfs*16 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | catalogued as rs765176430; called by mutect2, pindel
- PREX1 | c.4934C>A p.P1645Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64249848; called by muse, mutect2
- RBBP8 | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59091014; called by muse, mutect2
- RGR | c.214G>C p.A72P | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1393647169; called by muse, mutect2, varscan2
- SOHLH1 | c.942G>A p.W314* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100039774; called by muse, varscan2
- SVEP1 | c.1683C>T p.D561= | Splice Region (SNP) | VAF 13/51 reads (25%) | catalogued as rs75422692; called by muse, mutect2, varscan2
- TMEM223 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as COSV53667307, COSV99584823; called by muse, mutect2
- ZNF653 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV99542082; called by muse, mutect2
- ATP8B1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCNA2 | c.712T>C p.Y238H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FNIP1 | c.3025G>A p.V1009M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- MUC16 | c.4901C>A p.T1634K | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); called by muse, mutect2
- RAI1 | c.5640C>A p.Y1880* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- TBC1D8B | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- TICAM1 | c.1253C>A p.A418D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- FYN | c.1302C>A p.A434= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1178834184; called by muse, mutect2, varscan2
- KCND3 | c.1623C>A p.G541= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- SCYL2 | c.405T>C p.N135= | Silent (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- TGOLN2 | c.36C>A p.V12= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs1399905400, COSV56405790; called by muse, mutect2
- MARF1 | chr16:15643308 C>T | 5'Flank (SNP) | VAF 20/140 reads (14%) | catalogued as rs1339636515; called by muse, mutect2, varscan2
- OSGIN1 | n.500G>T | RNA (SNP) | VAF 14/112 reads (13%) | catalogued as COSV100652462; called by muse, mutect2
- STRN3 | c.282+11252C>A | Intron (SNP) | VAF 8/75 reads (11%) | catalogued as rs1214688306, COSV62578594; called by muse, mutect2, varscan2
